Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A5IV, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A5IV-01A (Primary Tumor).

[page 1 of 2]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

Specimen Inquiry

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] U #: [REDACTED]
REG DR: [REDACTED] AGE/SX: [REDACTED] ROOM: [REDACTED] REG: [REDACTED]
DOB: [REDACTED] BED: [REDACTED] DIS: [REDACTED]
STATUS: [REDACTED] TLOC: [REDACTED]

SPEC #: [REDACTED] PERFORMED AT [REDACTED]
TIME IN FORMALIN: 6:25 hrs.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon CA
Remarks:
Specimen(s): Right colectomy specimen

MICROSCOPIC DIAGNOSIS

RIGHT COLON AND PORTION OF TERMINAL ILEUM, RIGHT COLECTOMY:

- ADENOCARCINOMA OF TRANSVERSE COLON, LOW GRADE
- TUMOR MEASURES 9 CM AND INFILTRATES SUB SEROSA
- SURGICAL MARGINS FREE OF TUMOR
- NO TUMOR SEEN IN ANY OF 12 REGIONAL LYMPH NODES
- SEE COMMENT FOR SYNOPTIC REPORT

COMMENT(S)

CAP APPROVED SURGICAL PATHOLOGY CANCER CASE SUMMARY:

SPECIMEN:	Terminal ileum, cecum, ascending colon, transverse colon
PROCEDURE:	Right hemicolectomy
TUMOR SITE:	Transverse colon
TUMOR SIZE:	Greatest dimension: 9 cm
MACROSCOPIC TUMOR PERFORATION:	Not identified
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Low-grade
MICROSCOPIC TUMOR EXTENSION:	Tumor invades through the muscularis propria into the subserosal adipose tissue or the nonperitonealized pericolic or perirectal soft tissues, but does not extend to the serosal surface
MARGINS:	Proximal margin: Uninvolved by invasive carcinoma Distal margin: Uninvolved by invasive carcinoma Circumferential or Mesenteric Margin: Uninvolved by invasive carcinoma
LYMPH-VASCULAR INVASION:	Not identified
PERINEURAL INVASION:	Not identified
TUMOR DPOSITS:	Not identified
PATHOLOGIC STAGING:	Primary tumor: pT3 Regional lymph nodes: pN0 Number of lymph nodes examined: 12 Numbers of lymph nodes involved: 0

** CONTINUED ON NEXT PAGE **

ICD-O-3
Adenocarcinoma, NOS 8140/3
Site
Colon, Transverse colon C18.4
9/11/13

[page 2 of 2]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry

PAGE 2

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION:

The specimen is received in the fresh state from the operating room for immediate gross evaluation for tumor banking and consists of a right colectomy specimen. The colon measures 27 cm in length x 10 cm in circumference. Present in the distal portion of the colon is a fungating, red tumor which measures 9 x 6 x 3 cm, located 6 cm from the distal margin and 3 cm from the radial margin. The terminal ileum measures 14 cm in length x 4 cm in circumference x 1 cm in wall thickness and appears unremarkable. The appendix appears to be surgically absent. A representative section of the tumor is removed by aseptic technique, and the tumor obstructs the lumen, infiltrates the subserosa but does not appear to penetrate the visceral peritoneum. The following sections are submitted:

Block 1 - proximal margin
Block 2 - distal margin
Blocks 3-6 - colon tumor
Blocks 7-9 - whole lymph nodes
Block 10 - one lymph node trisected
Block 11 - one lymph node bisected
Block 12 - one lymph node trisected

Regional adipose tissue resected with the specimen measures 30 x 4 x 2 cm. A relatively small number of lymph nodes is present. These are soft and measure up to 1 cm.

INTRAOPERATIVE CONSULTATION:

IMMEDIATE GROSS EVALUATION:

- ADENOCARCINOMA PRESENT IN COLON, PROCESSED FOR TUMOR BANKING

Signed ____ (signature on file) ____

** END OF REPORT **

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file 9672f2af-2be3-4a35-b3be-e02c990ce7b9 (TCGA-NH-A5IV.F7280EE2-0A62-4DE5-8A20-17B6FBB51F41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).